Somatic mutation profile of tumor specimen MMRF_2590_1_BM_CD138pos (aliquot MMRF_2590_1_BM_CD138pos_T1_KHS5U_L12861) from MMRF case MMRF_2590, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.1 years (26,340 days).
Specimen MMRF_2590_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e00ce6c8-3e42-4d85-a14d-3a657a65920f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2590_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2590_1_PB_Whole_C3_KHS5U_L12862; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26d76a86-7d0b-44c7-9a90-537c7dc77c16

The open-access MAF lists 93 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 3'UTR 20, Intron 18, Silent 14, 5'UTR 6, 3'Flank 3, Frame Shift Ins 2, RNA 2, Splice Site 2, Splice Region 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.2379+2T>A p.X793_splice | Splice Site (SNP) | VAF 42/87 reads (48%) | catalogued as COSV54349860; called by muse, mutect2, varscan2
- G6PD | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as CM121672; called by muse, mutect2, varscan2
- GM2A | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as rs761084552; called by muse, mutect2, varscan2
- GRIA2 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 193/440 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99642745; called by muse, mutect2, varscan2
- NALCN | c.3842C>T p.T1281M | Missense Mutation (SNP) | VAF 79/88 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1304343682, COSV51950580; called by muse, varscan2
- PHF14 | c.2706G>C p.L902F | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101414607; called by muse, mutect2, varscan2
- SCNN1D | c.778G>A p.V260I (on ENST00000338555; = p.V424I on NM_001130413.4) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs763240072; called by muse, mutect2, varscan2
- SLC5A1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201079555, CM961328, COSV56686148; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as rs556509857, COSV64100553; called by muse, mutect2, varscan2
- TRAP1 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1316414429; called by muse, mutect2
- TTBK1 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs751441680, COSV52497963; called by muse, mutect2
- XDH | c.1748C>A p.A583E | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs1333577339; called by muse, mutect2, varscan2
- ZNF853 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1441976983; called by muse, mutect2, varscan2
- DDX6 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EVPL | c.5692_5708del p.N1898Hfs*63 | Frame Shift Del (DEL) | VAF 61/155 reads (39%) | called by mutect2, pindel, varscan2
- FAM200A | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FREM1 | c.3004G>C p.V1002L | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HEATR5A | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- IGLV4-60 | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- IGLV4-69 | c.49+2_49+6del p.X17_splice | Splice Site (DEL) | VAF 116/300 reads (39%) | called by pindel, varscan2
- KNCN | c.-1_3dup p.D2Hfs*122 (on ENST00000481882 / NM_001322255.2; = p.D2Hfs*99 on NM_001097611.1) | Frame Shift Ins (INS) | VAF 36/75 reads (48%) | called by mutect2, pindel, varscan2
- MARK1 | c.550A>C p.K184Q | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PAX1 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- POLR2B | c.1405-3T>C | Splice Region (SNP) | VAF 63/133 reads (47%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.872dup p.L291Ffs*4 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- TENT5A | c.241A>C p.T81P | Missense Mutation (SNP) | VAF 74/160 reads (46%) | called by muse, mutect2
- TMEM33 | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- UBXN7 | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- USH2A | c.10409T>A p.M3470K | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANK2 | c.11175G>A p.Q3725= | Silent (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- CDYL | c.723C>T p.V241= (on ENST00000328908 / NM_001368125.1; = p.V187= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs778741223; called by muse, mutect2, varscan2
- DLGAP1 | c.186C>T p.S62= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs886110395, COSV100227377; called by muse, mutect2, varscan2
- ELL2 | c.1152C>T p.P384= | Silent (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2
- FBXL18 | c.516C>T p.R172= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs1026995489; called by muse, mutect2, varscan2
- IGLC2 | c.297A>G p.T99= | Silent (SNP) | VAF 55/184 reads (30%) | called by muse, mutect2, varscan2
- IGSF11 | c.645C>T p.C215= (on ENST00000393775 / NM_001015887.3; = p.C214= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as rs762548204, COSV61170929; called by muse, mutect2, varscan2
- MIS18BP1 | c.99C>T p.S33= | Silent (SNP) | VAF 60/115 reads (52%) | called by muse, varscan2
- MUC3A | c.8703C>A p.T2901= | Silent (SNP) | VAF 132/1056 reads (13%) | called by muse, mutect2
- PAX1 | c.1239G>A p.G413= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs1378699862; called by muse, mutect2, varscan2
- PCDHB3 | c.978C>G p.G326= | Silent (SNP) | VAF 151/249 reads (61%) | catalogued as rs781795273; called by muse, mutect2, varscan2
- REG1B | c.120C>A p.T40= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100521320; called by muse, mutect2, varscan2
- TENT5A | c.243C>A p.T81= | Silent (SNP) | VAF 75/159 reads (47%) | called by muse, mutect2
- VGLL3 | c.843G>A p.K281= | Silent (SNP) | VAF 30/44 reads (68%) | called by muse, mutect2, varscan2
- AC005863.1 | n.1343A>C | RNA (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- ACAD10 | c.2818-507G>A | Intron (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*417C>T | 3'UTR (SNP) | VAF 39/81 reads (48%) | catalogued as rs569146974, COSV59506693; called by muse, mutect2, varscan2
- BMPR2 | c.*6762T>A | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- C2CD6 | c.1582-3626A>T | Intron (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- CDC42SE2 | c.*17+83T>A | Intron (SNP) | VAF 55/169 reads (33%) | called by muse, mutect2, varscan2
- CEP104 | c.1120-26T>A | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- CFDP1 | c.-99G>T | 5'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- DENND2A | c.2327+483C>T | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as rs1024036649; called by muse, mutect2, varscan2
- DNM1L | c.1674+134T>C | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- DOCK11 | c.*73T>G | 3'UTR (SNP) | VAF 87/228 reads (38%) | called by muse, mutect2, varscan2
- EIF3IP1 | n.527G>T | RNA (SNP) | VAF 55/198 reads (28%) | called by muse, mutect2, varscan2
- FAM43A | c.*711A>G | 3'UTR (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- GDA | c.*188G>T | 3'UTR (SNP) | VAF 22/64 reads (34%) | called by mutect2, varscan2
- GPM6B | c.-34G>A | 5'UTR (SNP) | VAF 180/450 reads (40%) | called by muse, mutect2
- HHIP | c.*2038del | 3'UTR (DEL) | VAF 32/59 reads (54%) | catalogued as rs536387324; called by mutect2, varscan2
- HTR2A | c.*199A>G | 3'UTR (SNP) | VAF 36/42 reads (86%) | called by muse, mutect2, varscan2
- IMPG1 | c.*492A>G | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- ITGA9 | c.1839+27C>T | Intron (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- KMT2C | c.14643+698A>G | Intron (SNP) | VAF 34/155 reads (22%) | called by muse, mutect2, varscan2
- LMO2 | c.42-243C>T | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- LMTK2 | c.-261T>C | 5'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- LSMEM1 | c.*22C>A | 3'UTR (SNP) | VAF 143/557 reads (26%) | called by muse, mutect2, varscan2
- MEF2C | c.402+113T>C | Intron (SNP) | VAF 71/203 reads (35%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851192 G>A | 5'Flank (SNP) | VAF 74/171 reads (43%) | catalogued as rs755938787; called by muse, mutect2, varscan2
- MMP15 | c.*1366T>G | 3'UTR (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- MYO7A | c.6051+43G>A | Intron (SNP) | VAF 60/127 reads (47%) | catalogued as rs367948124; called by muse, mutect2, varscan2
- NR2F2 | c.*2092C>T | 3'UTR (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*7495del | 3'UTR (DEL) | VAF 18/39 reads (46%) | catalogued as rs762233625; called by mutect2, varscan2
- P2RX1 | c.137+121T>G | Intron (SNP) | VAF 60/120 reads (50%) | called by muse, mutect2, varscan2
- PBX3 | c.*174A>C | 3'UTR (SNP) | VAF 39/153 reads (25%) | called by muse, mutect2, varscan2
- PCSK4 | c.1391+84C>T | Intron (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*6770T>C | 3'UTR (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- PRCD | chr17:76544870 G>A | 3'Flank (SNP) | VAF 36/75 reads (48%) | catalogued as rs1038519362; called by muse, mutect2, varscan2
- PSTPIP2 | c.*1055A>G | 3'UTR (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.-177C>G | 5'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs1035406500; called by muse, mutect2, varscan2
- RTL3 | c.*167G>T | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- SKIV2L | c.3399+23C>T | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2
- SLC5A12 | c.*3154A>G | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- SMARCC2 | c.493-92A>C | Intron (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- SNORA26 | chr4:52713419 T>C | 3'Flank (SNP) | VAF 84/179 reads (47%) | called by muse, mutect2, varscan2
- TCF4 | c.-96G>C | 5'UTR (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- TPGS2 | c.253+47G>T | Intron (SNP) | VAF 24/64 reads (38%) | called by muse, varscan2
- TRPS1 | chr8:115409691 T>A | 3'Flank (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- TTC17 | c.3151-87_3151-86del | Intron (DEL) | VAF 67/172 reads (39%) | called by pindel, varscan2
- USP38 | c.*105T>A | 3'UTR (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- WTAP | c.-415C>A | 5'UTR (SNP) | VAF 45/99 reads (45%) | catalogued as rs1162040872; called by muse, mutect2, varscan2
- ZIC4 | c.-15-1275C>T | Intron (SNP) | VAF 44/70 reads (63%) | catalogued as rs746844340; called by muse, mutect2, varscan2
- ZNF251 | c.*565G>T | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ZNF704 | c.*9311T>C | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
